Gene-level copy-number profile of tumor specimen TCGA-XV-AB01-06A from TCGA case TCGA-XV-AB01, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 54.9 years (20,058 days).
Specimen TCGA-XV-AB01-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.c327cb94-cf26-4174-8261-d3a6ed1cafdb.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XV-AB01-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate.
https://portal.gdc.cancer.gov/files/984650df-9a6e-478f-8de7-bae768a0455f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 25; copy number 2: 33,339; copy number 3: 20,864; copy number 4: 5,168; copy number 5: 247; copy number 19: 100.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 347 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:27,932,879–47,931,146, 237 genes, copy number 5 (broad region; genes not listed).
- chr18:48,147,634–48,184,725, 3 genes, copy number 5: AC105101.1, AC105101.2, RNU6-708P.
- chr18:73,711,329–74,160,531, 7 genes, copy number 5: AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21.
- chr22:40,410,281–40,636,719, 1 gene, copy number 19 (within-gene range 3–19): MRTFA.
- chr22:40,521,800–42,777,296, 99 genes, copy number 19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
